Somatic mutation profile of tumor specimen MP2PRT-PAUNHW-TMP1-A (aliquot MP2PRT-PAUNHW-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUNHW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,123 days).
Specimen MP2PRT-PAUNHW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 505a8ef6-c7a6-432b-8057-33d2dffa5e36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNHW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNHW-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/949d5f21-2137-46b1-83b2-3dc9ec523137

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.240G>A p.W80* | Nonsense Mutation (SNP) | VAF 74/350 reads (21%) | catalogued as COSV59371755; called by muse, mutect2, varscan2
- CCDC159 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1166372752; called by muse, mutect2
- DCAF12L1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 129/708 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284451282, COSV64422872; called by muse, mutect2, varscan2
- NGF | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1432643322, COSV65687789; called by muse, mutect2, varscan2
- POLA1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs138282947, COSV66888924; called by muse, mutect2, varscan2
- RB1 | c.1448dup p.H483Qfs*10 | Frame Shift Ins (INS) | VAF 16/157 reads (10%) | catalogued as rs34873197; called by mutect2, pindel, varscan2
- RIMS2 | c.2069C>T p.A690V (on ENST00000666250 / NM_001348490.2; = p.A498V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.714); catalogued as rs766459274; called by muse, mutect2, varscan2
- CTH | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); called by muse, mutect2
- MARK4 | c.31A>G p.N11D | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- PCDHB8 | c.2212G>T p.V738L | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.02); called by muse, mutect2
- PHRF1 | c.2939C>A p.A980D (on ENST00000264555 / NM_001286581.2; = p.A979D on NM_020901.4) | Missense Mutation (SNP) | VAF 156/736 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PIEZO2 | c.452_454del p.E151del | In Frame Del (DEL) | VAF 43/288 reads (15%) | called by mutect2, pindel, varscan2
- STK36 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ZDBF2 | c.310_320del p.E104Ifs*8 | Frame Shift Del (DEL) | VAF 44/357 reads (12%) | called by pindel, varscan2*
- GABBR2 | c.702C>T p.N234= | Silent (SNP) | VAF 28/371 reads (8%) | catalogued as rs759372813, COSV52316761; called by muse, mutect2
- MIA3 | c.1953G>T p.L651= | Silent (SNP) | VAF 49/390 reads (13%) | called by muse, mutect2, varscan2
- RBMXL3 | c.1461G>A p.S487= | Silent (SNP) | VAF 176/548 reads (32%) | catalogued as rs1482508722, COSV100407602; called by muse, mutect2, varscan2
- CLDN5 | c.-27C>T | 5'UTR (SNP) | VAF 22/736 reads (3%) | called by muse, mutect2
